Gene-level copy-number profile of tumor specimen TCGA-4Z-AA87-01A from TCGA case TCGA-4Z-AA87, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.4 years (26,430 days).
Specimen TCGA-4Z-AA87-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.1704a2ae-7b7a-4443-b78f-18af19a3a164.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA87-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6977543-b529-4a3c-8092-62b161a520c5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 383; copy number 2: 9,948; copy number 3: 24,203; copy number 4: 16,319; copy number 5: 4,260; copy number 6: 1,144; copy number 7: 822; copy number 8: 224; copy number 9: 896; copy number 10: 249; copy number 11: 55; copy number 12: 489; copy number 13: 49; copy number 14: 431; copy number 15: 39; copy number 16: 71; copy number 17: 114; copy number 25: 7; copy number 26: 33; copy number 27: 11; copy number 32: 8; copy number 33: 29; copy number 38: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA87-01A-11D-A390-01): tumor purity 0.61, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:31,925,801–32,272,301, 12 genes: AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,544 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,614,726–166,876,264, 378 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:171,444,699–172,752,924, 29 genes, copy number 12: CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1.
- chr2:70,149,885–74,970,128, 144 genes, copy number 7–17 (broad region; genes not listed).
- chr2:156,011,530–156,254,950, 1 gene, copy number 7 (within-gene range 4–7): LINC01876.
- chr2:156,305,108–159,904,756, 60 genes, copy number 7: AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1, CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2.
- chr3:3,066,324–34,873,854, 437 genes, copy number 7–16 (within-gene range 5–16) (broad region; genes not listed).
- chr3:61,561,569–65,053,439, 44 genes, copy number 8–12 (within-gene range 3–12): PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2.
- chr3:65,353,525–66,038,834, 1 gene, copy number 14 (within-gene range 3–14): MAGI1.
- chr3:65,687,301–66,009,200, 6 genes, copy number 14: ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1.
- chr3:75,435,232–75,538,029, 1 gene, copy number 7 (within-gene range 6–7): LINC02018.
- chr3:75,521,803–77,811,844, 24 genes, copy number 7: SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P.
- chr4:60,750,575–62,078,335, 7 genes, copy number 7 (within-gene range 6–7): LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1.
- chr4:86,823,468–87,391,188, 18 genes, copy number 7 (within-gene range 5–7): SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P.
- chr6:20,099,684–23,031,780, 32 genes, copy number 17–38 (within-gene range 3–38): MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1.
- chr8:99,695,957–107,498,055, 150 genes, copy number 10–17 (within-gene range 5–17) (broad region; genes not listed).
- chr9:452,492–12,300,451, 151 genes, copy number 7–17 (within-gene range 3–17) (broad region; genes not listed).
- chr9:20,999,509–22,029,594, 46 genes, copy number 8 (within-gene range 5–8): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr10:5,035,354–9,309,772, 89 genes, copy number 11–25 (broad region; genes not listed).
- chr10:25,647,570–27,542,239, 43 genes, copy number 12–32: GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A, GAD2, AL355798.1, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18.
- chr12:21,797,401–31,369,301, 168 genes, copy number 10–38 (broad region; genes not listed).
- chr12:31,396,390–31,465,842, 3 genes, copy number 10: RNU6-618P, AC068792.1, AC022080.1.
- chr12:32,790,755–34,249,958, 23 genes, copy number 11–16: PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr13:76,013,023–89,818,453, 131 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr15:97,339,693–97,523,442, 1 gene, copy number 7 (within-gene range 5–7): LINC02254.
- chr15:97,472,126–98,087,384, 12 genes, copy number 7: RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6.
- chr15:98,074,667–98,074,763, 1 gene, copy number 7: RNU6-1186P.
- chr15:100,400,395–101,933,350, 55 genes, copy number 7 (within-gene range 5–7): CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:30,115,521–30,186,475, 1 gene, copy number 7 (within-gene range 5–7): NSRP1.
- chr17:30,144,062–35,273,655, 191 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr17:54,899,387–61,392,838, 185 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr18:26,906,481–49,496,896, 283 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).
- chr19:29,213,235–30,713,538, 28 genes, copy number 12–13 (within-gene range 3–13): AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536.
- chr19:33,906,352–44,500,524, 559 genes, copy number 12–14 (within-gene range 5–14) (broad region; genes not listed).
- chr21:27,492,118–29,630,751, 34 genes, copy number 7: NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189, BACH1, GAPDHP14, BACH1-IT1, AP000240.1, BACH1-AS1, BACH1-IT2, BACH1-IT3.
- chr21:29,657,406–29,657,831, 1 gene, copy number 7: AP000238.1.
- chr21:30,089,717–30,289,514, 7 genes, copy number 7: AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1.
- chr21:30,487,043–38,156,511, 191 genes, copy number 7–9 (broad region; genes not listed).
- chr21:38,204,141–38,208,644, 2 genes, copy number 9: AP001425.1, DSCR10.
- chr21:39,745,407–39,802,096, 1 gene, copy number 8 (within-gene range 3–8): IGSF5.
- chr21:43,446,601–43,659,488, 6 genes, copy number 9 (within-gene range 3–9): LINC00319, LINC00313, AP001048.1, HSF2BP, RPL31P1, H2BS1.

Autosomal genes at a single copy (total copy number 1): 378. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
